Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAE2, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAE2-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma suggested

Specimen : Liver and Liver mass

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Partial hepatectomy

Organ: Liver (17.0 x 8.0 x 5.5 cm, 397.0 gm)

Gallbladder (9.5 cm in length, 3.5 cm in diameter, 0.6 cm in wall thickness)

[Liver]

Lesion: A hepatic mass

Size: 5.5 x 5.0 x 7.0 cm

Cut surface: Well demarcated, mahogany and nodular

Gross type: Multinodular confluent

Extent: Confined to the hepatic parenchyma

Serosal surface: Bulging but smooth

Resection margin: Not involved, grossly (safety margin: 0.1 cm)

Remaining parenchyme: Cirrhosis

[Gallbladder]

Serosal surface: Yellowish pink and smooth

Mucosal surface: Dark green and velvety

Stone: No stone

Representative sections submitted

Gross photo: Present

Blocks

T1-6, TB, mass of liver x 7

L, nontumorous liver parenchyme x 1

GB, gallbladder x 1

MICROSCOPIC:

Tumor type: Hepatocellular carcinoma

Edmondson-steiner grade

The worst differentiation II

The major differentiation III

Histologic type: Trabecular

Fatty change: No

Fibrous capsule formation: Yes

Capsular infiltration: No

Septum formation: No

Surgical resection margin invasion: No

Serosal invasion: No

Portal vein invasion: No

ICD-O.3

Carcinoma, hepatocellular NOS
8170/3

Date: Liver C22.0

Q4 5/20/14

[page 2 of 2]
Vascular invasion: No
Bile duct invasion: No
Remaining liver parenchyme: Cirrhosis

Parotid gland, aspiration, inflammation, atypical cells

NOT reported. Gross:

liver,ectomy,hepatocellular carcinoma
T56000, P10, M81703
gallbladder,ectomy,chronic cholecystitis,autolysis
T57000, P10, M43005, M54001
lymph node,biopsy,no tumor
T08000, P50, M09450

DIAGNOSIS:

Liver, partial hepatectomy:
Hepatocellular carcinoma, well differentiated

Gallbladder, cholecystectomy:
Chronic cholecystitis
Autolysis

Lymph node, pericystic, biopsy:
No tumor present (0/1)

Suggestion :

Source: NCI Genomic Data Commons file b169dcf7-5a42-4559-bed9-3b776ee1b044 (TCGA-DD-AAE2.C70F898B-E3C1-42C1-BF50-38E126A5B708.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).